Surgical pathology report (de-identified scan), TCGA case TCGA-J7-6720, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site ILSBio, specimen TCGA-J7-6720-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report
(For Collection of Cancerous Tissue)

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight		Blood Pressure	Heart Rate

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain ; blood in the urine
Symptoms: Fever ; Weight loss ;
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____	
		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status ☐ YES ☒ NO	TYPE	Packs/day	Duration (yrs)	When Quit (yr)
Alcohol Consumption				
Current Status ☐ YES ☒ NO	TYPE	Drinks/day	Duration (yrs)	When Quit (yr)
Drug Use				
Current Status ☐ YES ☒ NO	TYPE	Frequency	Duration (yrs)	When Quit (yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT ☒	A tumour in the left kidney	
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes		Location of Suspected Distant Metastasis
Clinical Staging		Date of Diagnosis
T1 N0 M0 Stage: I		

Treatment Information

SURGICAL TREATMENT					
Procedure			Date of Procedure		
Left Kidney Resection					
Primary Tumor					
Organ	Detailed Location	Size			
Kidney Tumor		3 x 2.5 x cm			
Extension of Tumor					
Lymph Nodes					
Description	Location of Lymph Nodes	# of Lymph Nodes			
Palpable, Non-Dissected Lymph Nodes					
Dissected Lymph Nodes					
Distant Metastasis					
Organ	Detailed Location	Size			
Surgical Staging					
T1 N0 M0 Stage: I					

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by:

Date:

Time:

Preserved by:

Date:

Time:

SPECIMEN TYPE (# of samples provided)

Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION

Primary Tumor

Organ	Size	Extension of Tumor	Distance to NAT
Kidney tumor	3 x 2.5 x cm		5 cm

Lymph Nodes

Location	# Examined	# Metastasized

Distant Metastasis

Organ	Detailed Location	Size

Pathological Staging

pT 1 N 0 M 0

Stage: I

Notes:

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION	+	-	STRUCTURAL PATTERN	+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis		X	Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized		X	Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	X		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	X		Fibroblast			Small Cell		
Keratin			Secretion	X		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	X		Lipoblast			Inflam. Cell		
Pearl			Gland formation		X	Myoblast			Plasma Cell		

Otherwise Specified:

D1 70% D2 70% D3 80% D4 70%

2. Cellular Differentiation:

Well	Moderately	Poor
X		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism		X		
Nucleolar Prominent		X		
Multinucleated Giant Cell		X		
Mitotic Activity		X		
Nuclear Grade				

Histological Diagnosis: *Papillary Renal Cell Carcinoma - G1*

Comments: _____

Date

Source: NCI Genomic Data Commons file fa627603-4f2e-47f2-8a9f-2e374ab224ab (TCGA-J7-6720.701DC72E-45EF-4C61-81BC-5697C37912D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).